Somatic mutation profile of tumor specimen TARGET-10-PATENL-04B (aliquot TARGET-10-PATENL-04B-01D) from TARGET case TARGET-10-PATENL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,345 days).
Specimen TARGET-10-PATENL-04B: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ab58614-ca9c-4711-88e0-32e14c3cf1c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATENL-10A (Blood Derived Normal), aliquot TARGET-10-PATENL-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/476bca5d-e928-438b-b776-04385c8a206b

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 10, Nonsense Mutation 3, Intron 2, 5'UTR 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PHF6 | c.673C>T p.R225* (on ENST00000332070 / NM_032458.3; = p.R226* on NM_032335.3) | Nonsense Mutation (SNP) | VAF 64/67 reads (96%) | catalogued as rs1556018932, COSV59699600; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLG | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs144799241; called by muse, mutect2
- LAMB4 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs768066977, COSV52713945; called by muse, mutect2, varscan2
- MYO7A | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782022331; called by muse, mutect2, varscan2
- NPY4R | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100966236; called by muse, mutect2, varscan2
- NT5C2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 65/309 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as rs1057519866, COSV58414509; ClinVar: not provided; called by muse, mutect2, varscan2
- PPM1N | c.441_442insCCCTAGATATAGA p.D148Pfs*2 | Nonsense Mutation (INS) | VAF 24/82 reads (29%) | catalogued as COSV55592645; called by mutect2, pindel, varscan2
- PPP1R16B | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1356816150, COSV55374369; called by muse, mutect2, varscan2
- RSPH3 | c.984G>T p.Q328H (on ENST00000252655; = p.Q186H on NM_031924.8) | Missense Mutation (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51924226; called by muse, mutect2, varscan2
- SDK1 | c.4367C>T p.T1456M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761730547, COSV67379272; called by muse, mutect2, varscan2
- ZBTB16 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60089398; called by muse, mutect2, varscan2
- ARHGEF12 | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CPA3 | c.343A>T p.S115C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CPVL | c.849G>C p.W283C | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DDX47 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FHOD1 | c.1961G>A p.W654* | Nonsense Mutation (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- GCC1 | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTR1B | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K20 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NCOA3 | c.2168A>G p.K723R | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHB1 | c.34A>T p.R12W | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PTEN | c.737dup p.L247Vfs*6 | Frame Shift Ins (INS) | VAF 16/166 reads (10%) | called by pindel, varscan2
- TRPM3 | c.1781G>A p.R594Q (on ENST00000357533 / NM_001366142.2; = p.R427Q on NM_020952.6) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ZC3H10 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- EIF4E3 | c.546C>G p.A182= (on ENST00000425534 / NM_001134651.2; = p.A76= on NM_173359.5) | Silent (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- FAM240A | c.111G>A p.R37= (on ENST00000444264; = p.R31= on NM_001195442.2) | Silent (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- MLPH | c.1281G>A p.A427= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs202229121, COSV52820316; called by muse, mutect2, varscan2
- NPNT | c.636T>C p.C212= | Silent (SNP) | VAF 24/209 reads (11%) | called by muse, mutect2, varscan2
- OPN5 | c.537C>T p.F179= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as rs755793601, COSV55245155; called by muse, mutect2, varscan2
- PEX5L | c.1596G>A p.T532= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1560166194; called by muse, mutect2, varscan2
- POU6F2 | c.1767T>C p.H589= | Silent (SNP) | VAF 7/200 reads (4%) | catalogued as COSV68868620; called by muse, mutect2
- TENM2 | c.6951C>T p.H2317= (on ENST00000518659 / NM_001122679.2; = p.H2078= on NM_001080428.3) | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as rs760505116; called by muse, mutect2, varscan2
- TRMT10C | c.465A>C p.A155= | Silent (SNP) | VAF 10/173 reads (6%) | called by muse, mutect2
- XDH | c.1089C>T p.P363= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs267599349, COSV65147139; called by muse, mutect2, varscan2
- ADGRL2 | c.-5C>T | 5'UTR (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CLEC16A | c.1815+83C>T | Intron (SNP) | VAF 98/161 reads (61%) | catalogued as rs868292891; called by muse, mutect2, varscan2
- LPO | c.76+51C>T | Intron (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- TRABD2A | chr2:84881089 C>T | 5'Flank (SNP) | VAF 3/10 reads (30%) | catalogued as rs1468267811; called by muse, mutect2
